Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA5N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA5N-01A (Primary Tumor).

ICD O-3

Carcinoma, urothelial NOS
8/20/13

Sites: Bladder NOS
C67.9

9/24/14

Specimen Comments

SPECIMEN

- A. Bladder tumour
- B. Left ureteric orifice biopsy

CLINICAL DETAILS

New bladder tumour occluding left ureteric orifice. Clinically HG + invasive while mass on EUA. Resection revealed ureter - resection border biopsied separately. ? T3 disease.

MACROSCOPY

- A. 3 g of firm tissue chippings.
- B. A single piece of tissue measuring 6 mm.

MICROSCOPY

A/B.

Site of tumour

Bladder

Growth pattern:

Infiltrating

Type:

Pw Tss,
5% signet ring.

High grade urothelial carcinoma with a signet ring differentiation. There is extensive necrosis.

Muscle present:

Yes

Stromal invasion:

Extensive muscle invasion is present (at least pT2).

Vascular Channel Invasion:

No definite lymphovascular invasion is identified.

Background Urothelium:

Cystitis cystica is identified within the background urothelium. A small area of carcinoma in-situ is identified within the main specimen.

The left ureteric orifice biopsy identified separately (specimen B) shows no definite evidence of carcinoma in-situ and no invasive disease.

SUMMARY:

Bladder; High Grade Urothelial Carcinoma, G3, pT2 (at least) with CIS.

Ref:

Pathologists -

Source: NCI Genomic Data Commons file 1463d3a4-f615-4dd5-aae4-506ff901f904 (TCGA-ZF-AA5N.C115F113-1A42-4DB6-A6AA-7717C6DE227C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).